Somatic mutation profile of tumor specimen MP2PRT-PAVWZE-TMP1-A (aliquot MP2PRT-PAVWZE-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVWZE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,114 days).
Specimen MP2PRT-PAVWZE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8181d4b2-b1c4-4406-bc57-d279755aad41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWZE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWZE-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46e3733e-d379-4299-bc98-33acc56ba751

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.10327G>A p.V3443I | Missense Mutation (SNP) | VAF 161/481 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs780591643, COSV100318996, COSV60917774; called by muse, mutect2, varscan2
- CADM2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 212/561 reads (38%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.057); catalogued as COSV67388535; called by muse, mutect2, varscan2
- FAXC | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs369719974; called by muse, mutect2, varscan2
- NPAP1 | c.2692C>A p.H898N | Missense Mutation (SNP) | VAF 219/495 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV61507349; called by muse, mutect2, varscan2
- PAX5 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 170/360 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63905332; called by muse, mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 125/437 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2, varscan2
- KCNB1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 276/640 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POU4F1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 174/366 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); called by muse, varscan2
- SLIT1 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 130/160 reads (81%) | called by muse, mutect2, varscan2
- METRNL | c.303C>T p.A101= | Silent (SNP) | VAF 28/856 reads (3%) | called by muse, mutect2
- ZNF804A | c.3582A>C p.S1194= | Silent (SNP) | VAF 187/422 reads (44%) | called by muse, mutect2, varscan2
- IGHV1-58 | chr14:106627248 ins GCCTA | 5'Flank (INS) | VAF 89/176 reads (51%) | called by mutect2, pindel, varscan2
